Somatic mutation profile of tumor specimen TCGA-MU-A8JM-01A (aliquot TCGA-MU-A8JM-01A-11D-A36J-09) from TCGA case TCGA-MU-A8JM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 47.0 years (17,156 days).
Specimen TCGA-MU-A8JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e249b8e-517a-465e-9461-f1f7df21c889.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MU-A8JM-10A (Blood Derived Normal), aliquot TCGA-MU-A8JM-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/667e55cc-f8ea-497b-b34d-112d32dc7fc6

The open-access MAF lists 115 somatic variants for this specimen: 79 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 32, Nonsense Mutation 8, Splice Region 3, Splice Site 2, RNA 2, Frame Shift Ins 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD9 | c.1766-1G>T p.X589_splice | Splice Site (SNP) | VAF 16/124 reads (13%) | catalogued as COSV100459415; called by muse, mutect2, varscan2
- ACTL9 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV61005400; called by muse, mutect2, varscan2
- ADGRD1 | c.2480C>A p.T827K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV99896942; called by muse, mutect2, varscan2
- ALOX12B | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs1276974165, COSV100047680; called by muse, mutect2, varscan2
- ATAD2 | c.3470G>A p.S1157N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); catalogued as COSV99785253; called by muse, mutect2, varscan2
- ATG2B | c.3128C>G p.S1043C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV100738154, COSV100738233; called by muse, mutect2, varscan2
- BOD1L1 | c.4357G>A p.E1453K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99240344; called by muse, mutect2, varscan2
- CCDC116 | c.1310A>G p.D437G | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV53040885, COSV99489497; called by muse, mutect2, varscan2
- CD8B | c.667C>A p.H223N (on ENST00000331469 / NM_172213.4; = p.H193N on NM_172102.4) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100514717; called by muse, mutect2, varscan2
- CDK12 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 41/133 reads (31%) | catalogued as COSV101420528; called by muse, mutect2, varscan2
- CENPE | c.5101G>C p.E1701Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV54390198, COSV99478375, COSV99479049; called by muse, mutect2, varscan2
- CFAP43 | c.4769G>A p.S1590N | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV100829470; called by muse, mutect2, varscan2
- COL19A1 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 39/110 reads (35%) | catalogued as rs866179157, COSV59586186; called by muse, mutect2, varscan2
- COL6A1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs751417733, COSV100720455; called by muse, mutect2, varscan2
- DEPDC5 | c.1906G>C p.E636Q (on ENST00000400246; = p.E714Q on NM_014662.5) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.026); catalogued as COSV99836485; called by muse, varscan2
- DNASE2B | c.363C>A p.S121R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.549); catalogued as COSV101042137; called by muse, mutect2, varscan2
- EFCAB12 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100394804, COSV58178783; called by muse, mutect2, varscan2
- EIF2S2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100895008, COSV66622136; called by muse, mutect2, varscan2
- FIBCD1 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs945498576, COSV53395796; called by muse, mutect2, varscan2
- FSCB | c.2363C>T p.S788L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100469826, COSV61217916; called by muse, mutect2, varscan2
- FZD4 | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.514); catalogued as COSV72294651; called by muse, mutect2, varscan2
- GRAMD1A | c.1578G>A p.L526= | Splice Region (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100526409; called by muse, mutect2, varscan2
- GRK7 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV99380236; called by muse, mutect2, varscan2
- GRK7 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV99380238; called by muse, mutect2, varscan2
- HELZ | c.2437C>T p.Q813* | Nonsense Mutation (SNP) | VAF 33/99 reads (33%) | catalogued as COSV100699039; called by muse, mutect2, varscan2
- IREB2 | c.2336G>A p.R779H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99359391; called by muse, mutect2, varscan2
- ISLR | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); catalogued as rs527446512, COSV99997549; called by muse, mutect2, varscan2
- ITGB3BP | c.533G>A p.*178= | Splice Region (SNP) | VAF 49/168 reads (29%) | catalogued as COSV99371307; called by muse, mutect2, varscan2
- KALRN | c.3211C>T p.R1071W | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99563721; called by muse, mutect2, varscan2
- KLHL32 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs781002914, COSV100987209; called by muse, mutect2, varscan2
- KRTAP21-2 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as rs750056609, COSV61683898; called by muse, mutect2, varscan2
- LAMB4 | c.4004C>T p.S1335F | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV52726314; called by muse, mutect2, varscan2
- LMBR1L | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.192); catalogued as COSV99918989; called by muse, mutect2, varscan2
- LONP2 | c.2326C>T p.L776F | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99589500; called by muse, mutect2, varscan2
- LYN | c.633C>A p.Y211* | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as COSV101319637; called by muse, mutect2, varscan2
- MAGEB3 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs746598074, COSV64397357; called by muse, mutect2, varscan2
- MIDEAS | c.1867G>C p.V623L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as COSV99679215; called by muse, mutect2, varscan2
- MRPL22 | c.231C>G p.S77R | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99501800; called by muse, mutect2, varscan2
- MUC16 | c.794T>C p.F265S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as COSV101201475; called by muse, mutect2, varscan2
- NACA | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs1361647025, COSV100771614; called by muse, mutect2, varscan2
- NEURL2 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs772492087, COSV99510127; called by muse, mutect2, varscan2
- NEURL2 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV51942298, COSV99510128; called by muse, mutect2, varscan2
- NKTR | c.2306C>T p.S769L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV51769331; called by muse, mutect2, varscan2
- NOD1 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs754320439, COSV56115671; called by muse, mutect2, varscan2
- NOTCH1 | c.5123C>T p.S1708L | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.821); catalogued as rs778830490, COSV53075176; called by muse, mutect2, varscan2
- NTAN1 | c.831dup p.H278Tfs*13 | Frame Shift Ins (INS) | VAF 30/91 reads (33%) | catalogued as rs780770021; called by mutect2, varscan2
- NUP205 | c.2162C>T p.S721F | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as COSV53658668, COSV99607563; called by muse, mutect2, varscan2
- OR5R1 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV100393204, COSV100393583; called by muse, mutect2, varscan2
- OR8B12 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100172937; called by muse, mutect2, varscan2
- PCDHB8 | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 40/528 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.458); catalogued as COSV99177345; called by muse, mutect2
- PCLO | c.2274G>C p.K758N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); catalogued as COSV100437468; called by muse, mutect2, varscan2
- PCNX1 | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV99457142; called by muse, mutect2, varscan2
- PLA1A | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs769912624, COSV99846059; called by muse, mutect2, varscan2
- PNLDC1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99277857; called by muse, mutect2, varscan2
- PPIL6 | c.632-1G>A p.X211_splice | Splice Site (SNP) | VAF 15/57 reads (26%) | catalogued as COSV101329713; called by muse, mutect2, varscan2
- RBPMS | c.50A>C p.N17T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99824497; called by muse, mutect2, varscan2
- RIN3 | c.2356G>T p.D786Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99379997; called by muse, mutect2, varscan2
- RTP2 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as rs1382072552, COSV100833009; called by muse, mutect2, varscan2
- SLC26A4 | c.603G>A p.L201= | Splice Region (SNP) | VAF 16/61 reads (26%) | catalogued as COSV55914188, COSV99707483; called by muse, mutect2, varscan2
- SLC28A2 | c.1170G>C p.K390N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as rs759432504, COSV100754807, COSV100754841; called by muse, mutect2, varscan2
- SLC4A1 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as COSV99293657; called by muse, mutect2, varscan2
- SLCO6A1 | c.2105C>A p.P702Q | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV101134945, COSV65808329; called by muse, mutect2, varscan2
- SNAI3 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100178974; called by muse, mutect2, varscan2
- SNRNP25 | c.241G>A p.E81K (on ENST00000383018; = p.E72K on NM_024571.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as COSV99245108; called by muse, mutect2, varscan2
- SRCAP | c.8764C>T p.Q2922* | Nonsense Mutation (SNP) | VAF 9/99 reads (9%) | catalogued as COSV99351258; called by muse, mutect2
- STK26 | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV100688882; called by muse, mutect2, varscan2
- TFG | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 26/208 reads (13%) | catalogued as COSV52544513; called by muse, mutect2, varscan2
- TMEM25 | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV100244922; called by muse, mutect2, varscan2
- TNK2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.018); catalogued as rs748682309, COSV100361523, COSV100361664; called by muse, mutect2, varscan2
- TRAPPC9 | c.2194C>T p.Q732* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as rs139179950; called by muse, mutect2, varscan2
- TTLL5 | c.1472C>A p.T491K | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100091489; called by muse, mutect2, varscan2
- WEE1 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV100219821; called by muse, mutect2
- WNK1 | c.6205G>A p.D2069N (on ENST00000315939 / NM_018979.4; = p.D1821N on NM_014823.3) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100268518, COSV60032084; called by muse, mutect2, varscan2
- YY2 | c.425G>T p.S142I | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.396); catalogued as rs1407080696, COSV100810846; called by muse, mutect2, varscan2
- ZBED4 | c.272G>T p.S91I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as COSV99351657; called by muse, mutect2
- ZNF501 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101247156; called by muse, mutect2, varscan2
- ZNF569 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.765); catalogued as COSV57596358; called by muse, mutect2, varscan2
- PHRF1 | c.1701_1702insGCCGG p.S568Afs*35 (on ENST00000264555 / NM_001286581.2; = p.S567Afs*35 on NM_020901.4) | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- RBPJ | c.542_550delinsAA p.I181Kfs*23 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by pindel, varscan2*
- A4GALT | c.1035G>T p.T345= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as COSV99966764; called by muse, mutect2, varscan2
- ANKRD30A | c.1107T>C p.S369= (on ENST00000611781; = p.S313= on NM_052997.2) | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as COSV100654413; called by muse, mutect2, varscan2
- BRI3 | c.285C>T p.I95= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs766685450, COSV50060984, COSV99134809; called by muse, mutect2, varscan2
- C1QC | c.705C>T p.S235= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs771395443, COSV101009547; called by muse, mutect2, varscan2
- CAMSAP3 | c.3483C>G p.L1161= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV50330841, COSV99351515; called by muse, mutect2, varscan2
- CCDC113 | c.732C>T p.T244= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs1567501480; called by muse, mutect2
- CKAP5 | c.4734C>T p.S1578= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs772497527, COSV100371409; called by muse, mutect2, varscan2
- CSMD1 | c.2676C>T p.I892= (on ENST00000520002; = p.I891= on NM_033225.6) | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs1158650107, COSV100153369; called by muse, mutect2, varscan2
- CYP7B1 | c.960C>T p.D320= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV59587784; called by muse, mutect2, varscan2
- DPYSL3 | c.1176C>T p.F392= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100575372; called by muse, mutect2, varscan2
- DRC7 | c.2307G>T p.A769= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV61055042; called by muse, mutect2, varscan2
- DUSP29 | c.372C>T p.F124= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs768081073, COSV100633404; called by muse, mutect2, varscan2
- ELAPOR2 | c.2184T>C p.A728= (on ENST00000450689 / NM_001142749.3; = p.A561= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV99789359; called by muse, mutect2, varscan2
- FLT3 | c.1668C>T p.V556= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as rs777127892, COSV54058658; called by muse, mutect2, varscan2
- GRIA1 | c.1828C>T p.L610= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99602218; called by muse, mutect2, varscan2
- GRK7 | c.30G>A p.L10= | Silent (SNP) | VAF 34/226 reads (15%) | catalogued as COSV99380232; called by muse, varscan2
- GZMM | c.225G>T p.L75= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV52741773; called by muse, mutect2, varscan2
- HACD3 | c.690C>T p.I230= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99971292; called by muse, mutect2, varscan2
- HDAC7 | c.2175C>T p.L725= (on ENST00000427332; = p.L764= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs756075583, COSV99316878; called by muse, mutect2, varscan2
- KLHDC7B | c.952C>T p.L318= (on ENST00000395676; = p.L959= on NM_138433.5) | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as rs1174804934, COSV101192983; called by muse, mutect2, varscan2
- MYH2 | c.2454C>T p.F818= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV99819125; called by muse, mutect2, varscan2
- MYO1B | c.93C>T p.F31= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV100270019; called by muse, mutect2, varscan2
- NGF | c.402G>A p.S134= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs565841831, COSV101049610; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLN | c.2026C>T p.L676= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV101114467; called by muse, mutect2, varscan2
- RMND1 | c.402A>G p.T134= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs757664665, COSV100323801; called by muse, mutect2, varscan2
- TM4SF18 | c.297C>T p.L99= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as rs769129238, COSV56059562; called by muse, mutect2, varscan2
- UBR4 | c.6297G>A p.L2099= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV100921789, COSV64382091; called by muse, mutect2, varscan2
- UCN3 | c.6G>C p.L2= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100991738; called by muse, mutect2, varscan2
- WDFY3 | c.2064G>T p.V688= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs759714006, COSV99885532; called by muse, mutect2, varscan2
- ZNF142 | c.948G>A p.E316= (on ENST00000411696 / NM_001379660.1; = p.E116= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV101376995; called by muse, mutect2, varscan2
- ZNF43 | c.1353G>A p.E451= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100731958, COSV61685799; called by muse, mutect2, varscan2
- ZSCAN21 | c.1110C>T p.S370= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs369446597; called by muse, mutect2, varscan2
- CAMKK1 | c.685+263C>T | Intron (SNP) | VAF 13/37 reads (35%) | catalogued as rs376647697; called by muse, mutect2, varscan2
- DCHS2 | n.1907C>T | RNA (SNP) | VAF 15/42 reads (36%) | catalogued as COSV59722046; called by muse, mutect2, varscan2
- MAZ | c.1280-431G>A | Intron (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99361474; called by muse, mutect2, varscan2
- SSPOP | n.3477G>C | RNA (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100022965; called by muse, mutect2, varscan2
